Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A700, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A700-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology	Final Results
Surgical Pathology	Final

CASE NUMBER:
DIAGNOSIS:

1. Mass, left omental, frozen section: Fat necrosis.
2. Spleen, frozen section, resection: Low grade B cell Lymphoma with CD5 expression; see Note.
3. Adrenal gland, left, resection:
- Pheochromocytoma; see Note.
- Adipose tissue involved by low grade B cell lymphoma.

NOTE:

Specimen #2 was reviewed by _____ hematopathologist.

H
atypical lymphoid cells in the red pulp. The atypical lymphoid cells range in size from medium sized to large, they have abundant pale cytoplasm.

Immunohistochemistry studies were performed for CD20, CD5, CD3, CD21, CD23, IgD, MIB-1 and cyclinD1. The atypical lymphoid cells are CD20 positive, CD5 and CD23. CD3 and CD5 highlight background T cells. CD 21 demonstrates residual follicular dendritic cell meshworks. The atypical cells are negative for cyclinD1 and IgD. A moderate proliferation rate is illustrated by the MIB-1 immunostain.

We favor a diagnosis of low grade B cell lymphoma; the differential diagnoses include splenic marginal zone lymphoma, chronic lymphocytic leukemia/small lymphocytic lymphoma (CLL/SLL) and mantle cell lymphoma. Negativity for cyclinD1 argues against a mantle cell lymphoma. The pattern of involvement is more in favor of a splenic marginal zone lymphoma than CLL/SLL (i.e. the clusters of atypical cells in the red pulp and the predominant involvement of the white pulp). CD5 positivity can be seen in marginal zone lymphoma.

In specimen #2, the pheochromocytoma shows nested tumor cells that are positive for chromogranin and synaptophysin. Surrounding adipose tissue is infiltrated by atypical monotonous lymphoid cells that are CD20 positive.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology, _____. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: _____ Brief
Clinical History: adrenal
mass, previous biopsy of surrounding retroperitoneal lymph nodes
consistent with B cell lymphoma Specimen Taken For Protocol: 01 - Yes

Requested By:

Do not file in Medical Record

[page 2 of 3]
PROCEDURE: Pre-Operative Diagnosis: adrenal mass Post-Operative
Diagnosis: same
Operative Findings: soft adrenal mass, large spleen with superficial
changes

SPECIMENS SUBMITTED: 1. OMENTUM, Mass (1FS)
2. SPLEEN, (2FS)
3. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received are 3 specimens labeled with the patient's
name, medical record number, and further specified as follows:

1. "Left omental mass FS". The specimen is in a green cassette labeled
with the patient's name, and date of _____. The specimen is
transferred from a green cassette to an orange cassette labeled
_____. The remaining specimen is submitted for permanent
processing in white cassettes labeled _____.

2. "Spleen". The specimen is a spleen. Please defer to description
under intraoperative consultation. The frozen section is transferred
from a green cassette labeled with the patient's name, date and _____ to
an orange cassette labeled as _____. The remaining specimen of
the spleen is further sectioned to reveal a small area measuring 3 cm
in greatest dimension. The remaining surface of the spleen has very
prominent white pulp. The specimen is sampled as follows: _____ and
sampling of hemorrhagic lesion. _____ sampling of spleen
parenchyma with prominent white pulp (does not have hemorrhagic
lesion). Sampling of fat surrounding the splenic sinus. Also
received, yet entirely submitted for research, labeled "abdominal wall
fat" is a normal-appearing adipose tissue fragment, 1.2 x 1.1 x 0.5 cm;
entirely procured for _____ on _____.

3. "Left adrenal mass" is an adrenalectomy specimen weighing 82.1 grams,
reddish-orange in color. The specimen measures 10.5 cm x 4 cm x 2.0
cm. The outer surface of one side is inked blue. The specimen is cut
revealing a white cut surface with a rim of normal-appearing adrenal.
Approximately 2 cm x 2 cm x 2 cm tissue is procured for
lab. 1 x 1 x 1 cm is procured for _____. The procurement was
performed by _____ on _____. The specimen
is received in Surgical Pathology and matches the above description.
The entire outer surface of the specimen is inked in blue. The
specimen is serially sectioned. The specimen is sampled as follows:
normal-appearing adrenal. _____ Normal-appearing adrenal gland. The
_____ mass appears nodular in place. The mass is further sampled
in white cassettes _____. Appears to be encapsulated. _____ is mass in
relation to adrenal.

Gross Description dictated by _____

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By: _____

Do not file in Medical Record

[page 3 of 3]
Surgical Pathology**Final Results**

Please note at the present time of transcription of this case, there is no intraoperative tab to enter this frozen diagnosis, so it is placed here, but it needs to be moved when the entry tab is placed for this specimen on this report.

Received fresh from OR labeled with the patient's name, medical record number, and further specified as "left omental mass" is a variegated yellow-red soft tissue fragment measuring 1.4 x 1 cm x 0.5 cm. It is bisected revealing a firm, white-yellow nodule, measuring 1 cm x 0.5 x 0.5 cm. Half of the nodule is frozen as

1FS Diagnosis: Favor fat necrosis.

2. "Spleen" is a splenectomy specimen weighing 467 grams and measuring 13.5 x 12 cm x 5 cm with a small amount of fat. The capsule presents an area of fibrosis measuring 5.5 cm x 7 cm near the fat. The capsule is inked in black and section is submitted as 2FS.

2FS Diagnosis: Atypical lymphocytosis, defer to permanent.

The intraoperative consults were done by _____ and _____

Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Histology Discrepancy		✓
Dual/Synchronous Primary Noted as Lymphoma		✓

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file de92593c-4ccb-4712-954c-001a47629253 (TCGA-QR-A700.88FDD899-BC1A-4FC9-946E-2889BB7EE8C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).